Somatic mutation profile of tumor specimen TCGA-LG-A9QD-01A (aliquot TCGA-LG-A9QD-01A-11D-A382-10) from TCGA case TCGA-LG-A9QD, project TCGA-LIHC (Liver Hepatocellular Carcinoma). Sex at birth: male; Vital status: Alive; Primary diagnosis: Hepatocellular carcinoma, NOS; Tissue or organ of origin: Liver; AJCC pathologic stage: Stage IIIA; Tumor grade: G2; Age at diagnosis: 68.4 years (24,969 days).
Specimen TCGA-LG-A9QD-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: OCT.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 579ce8b5-5d20-4d7e-a367-638bdc70747c.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-LG-A9QD-10A (Blood Derived Normal), aliquot TCGA-LG-A9QD-10A-01D-A385-10; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/06863faf-a171-46c1-8c9c-7f15b2d7b51b

The open-access MAF lists 118 somatic variants for this specimen: 87 protein-altering or splice-affecting, 31 silent.
By variant classification: Missense Mutation 73, Silent 31, Splice Site 4, Nonsense Mutation 4, Frame Shift Del 4, In Frame Del 2.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- CTNNB1 | c.134C>T p.S45F | Missense Mutation (SNP) | VAF 47/146 reads (32%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (0.928); catalogued as rs121913409, COSV62687872, COSV62688307, COSV62689938, COSV62711475; ClinVar: other / pathogenic / likely pathogenic; called by muse, mutect2, varscan2
- JAK1 | c.2729T>C p.L910P | Missense Mutation (SNP) | VAF 24/107 reads (22%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV61090359; called by muse, mutect2, varscan2
- AC244197.3 | c.973T>C p.Y325H | Missense Mutation (SNP) | VAF 40/62 reads (65%) | SIFT tolerated (0.21); PolyPhen benign (0.046); catalogued as COSV100557807; called by muse, mutect2, varscan2
- ACTBL2 | c.1099G>A p.G367S | Missense Mutation (SNP) | VAF 18/86 reads (21%) | SIFT deleterious, low confidence (0.01); PolyPhen probably damaging (0.944); catalogued as COSV101379216; called by muse, mutect2, varscan2
- ACTN2 | c.876+1G>T p.X292_splice | Splice Site (SNP) | VAF 32/100 reads (32%) | catalogued as COSV100856501; called by muse, varscan2
- ALB | c.1289+2T>G p.X430_splice | Splice Site (SNP) | VAF 54/192 reads (28%) | catalogued as COSV99890609; called by muse, mutect2, varscan2
- ARHGAP10 | c.830A>G p.K277R | Missense Mutation (SNP) | VAF 154/537 reads (29%) | SIFT deleterious (0); PolyPhen possibly damaging (0.906); catalogued as COSV100330839; called by muse, mutect2, varscan2
- ATP10B | c.4009C>T p.L1337F | Missense Mutation (SNP) | VAF 18/98 reads (18%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.946); catalogued as COSV100514008; called by muse, mutect2, varscan2
- C14orf39 | c.341A>G p.Y114C | Missense Mutation (SNP) | VAF 44/187 reads (24%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.991); catalogued as COSV100407191; called by muse, mutect2, varscan2
- C1R | c.2053A>T p.T685S (on ENST00000536053 / NM_001354346.2; = p.T671S on NM_001733.7) | Missense Mutation (SNP) | VAF 36/120 reads (30%) | SIFT tolerated (0.05); PolyPhen benign (0.442); catalogued as COSV101605601; called by muse, mutect2, varscan2
- C1orf87 | c.139C>T p.Q47* | Nonsense Mutation (SNP) | VAF 36/122 reads (30%) | catalogued as COSV100966898; called by muse, mutect2, varscan2
- C2CD2L | c.142C>T p.P48S | Missense Mutation (SNP) | VAF 8/35 reads (23%) | SIFT tolerated (0.29); PolyPhen benign (0); catalogued as rs775703202, COSV100371044; called by muse, mutect2, varscan2
- C2CD5 | c.462A>C p.K154N | Missense Mutation (SNP) | VAF 30/92 reads (33%) | SIFT tolerated (0.51); PolyPhen benign (0.015); catalogued as COSV100448424; called by muse, mutect2, varscan2
- CENATAC | c.88C>G p.L30V | Missense Mutation (SNP) | VAF 44/134 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as COSV100548600; called by muse, mutect2, varscan2
- CEP57 | c.1403T>G p.L468R | Missense Mutation (SNP) | VAF 104/384 reads (27%) | SIFT tolerated (0.27); PolyPhen benign (0); catalogued as COSV100334551; called by muse, mutect2, varscan2
- CKAP5 | c.1603A>G p.I535V | Missense Mutation (SNP) | VAF 28/104 reads (27%) | SIFT tolerated (0.42); PolyPhen benign (0); catalogued as COSV100370323; called by muse, mutect2, varscan2
- CNN2 | c.539G>A p.G180D | Missense Mutation (SNP) | VAF 28/91 reads (31%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.989); catalogued as COSV99565054; called by muse, mutect2, varscan2
- COL12A1 | c.197C>T p.P66L | Missense Mutation (SNP) | VAF 19/81 reads (23%) | SIFT tolerated (0.05); PolyPhen probably damaging (0.93); catalogued as COSV100485294; called by muse, mutect2, varscan2
- COQ7 | c.142G>A p.A48T | Missense Mutation (SNP) | VAF 31/133 reads (23%) | SIFT tolerated (0.44); PolyPhen benign (0.001); catalogued as rs1416114529, COSV100430452; called by muse, mutect2, varscan2
- DCC | c.392C>G p.T131R | Missense Mutation (SNP) | VAF 32/123 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (0.917); catalogued as COSV100497880; called by muse, mutect2, varscan2
- DGKH | c.628A>G p.K210E | Missense Mutation (SNP) | VAF 12/37 reads (32%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.98); catalogued as rs1179848706, COSV99818203; called by muse, mutect2, varscan2
- DHRS1 | c.794G>C p.R265P | Missense Mutation (SNP) | VAF 32/88 reads (36%) | SIFT tolerated (0.13); PolyPhen benign (0.206); catalogued as COSV99852130; called by muse, mutect2, varscan2
- DIDO1 | c.2973G>A p.M991I | Missense Mutation (SNP) | VAF 29/70 reads (41%) | SIFT tolerated (0.43); PolyPhen benign (0); catalogued as COSV99824514; called by muse, mutect2, varscan2
- DLG3 | c.563A>C p.E188A | Missense Mutation (SNP) | VAF 16/31 reads (52%) | SIFT deleterious (0); PolyPhen possibly damaging (0.544); catalogued as COSV99529143; called by muse, mutect2, varscan2
- DRC7 | c.8T>C p.V3A | Missense Mutation (SNP) | VAF 26/77 reads (34%) | SIFT deleterious, low confidence (0.01); PolyPhen probably damaging (0.98); catalogued as COSV100395340; called by muse, mutect2, varscan2
- FBXO8 | c.315A>C p.E105D | Missense Mutation (SNP) | VAF 34/152 reads (22%) | SIFT tolerated (0.17); PolyPhen benign (0.057); catalogued as COSV101183613; called by muse, mutect2, varscan2
- FGG | c.673del p.D225Mfs*4 | Frame Shift Del (DEL) | VAF 8/34 reads (24%) | catalogued as COSV60194425; called by mutect2, pindel, varscan2
- GALNTL5 | c.961G>T p.E321* | Nonsense Mutation (SNP) | VAF 49/182 reads (27%) | catalogued as COSV67180664; called by muse, mutect2, varscan2
- GGA1 | c.194A>T p.Q65L | Missense Mutation (SNP) | VAF 22/96 reads (23%) | SIFT deleterious (0.01); PolyPhen benign (0.394); catalogued as COSV100289626; called by muse, mutect2, varscan2
- IDI1 | c.53G>T p.R18L | Missense Mutation (SNP) | VAF 20/69 reads (29%) | SIFT tolerated, low confidence (0.4); PolyPhen benign (0.009); catalogued as COSV100830131; called by muse, mutect2, varscan2
- IL24 | c.259A>T p.T87S | Missense Mutation (SNP) | VAF 18/68 reads (26%) | SIFT tolerated (0.07); PolyPhen benign (0.098); catalogued as COSV99686360; called by muse, mutect2, varscan2
- IL31 | c.224C>T p.P75L | Missense Mutation (SNP) | VAF 37/123 reads (30%) | SIFT tolerated (0.51); PolyPhen benign (0.01); catalogued as COSV100986554; called by muse, mutect2, varscan2
- ITGAE | c.508G>A p.D170N | Missense Mutation (SNP) | VAF 11/30 reads (37%) | SIFT tolerated (0.89); PolyPhen benign (0); catalogued as rs184355144, COSV53999269; called by muse, mutect2, varscan2
- KCNJ16 | c.922C>T p.H308Y | Missense Mutation (SNP) | VAF 28/132 reads (21%) | SIFT tolerated (0.06); PolyPhen benign (0.01); catalogued as COSV99387893; called by muse, mutect2, varscan2
- KCNJ6 | c.1256A>G p.N419S | Missense Mutation (SNP) | VAF 10/44 reads (23%) | SIFT tolerated, low confidence (1); PolyPhen benign (0); catalogued as COSV99899019; called by muse, mutect2, varscan2
- KRTAP6-1 | c.35C>T p.T12I | Missense Mutation (SNP) | VAF 33/113 reads (29%) | PolyPhen benign (0.025); catalogued as rs1462335155, COSV58167943; called by muse, mutect2, varscan2
- LCE2D | c.155C>G p.S52C | Missense Mutation (SNP) | VAF 41/158 reads (26%) | SIFT tolerated, low confidence (0.08); PolyPhen probably damaging (0.966); catalogued as COSV100909517; called by muse, mutect2, varscan2
- LMX1B | c.89T>C p.M30T | Missense Mutation (SNP) | VAF 19/71 reads (27%) | SIFT deleterious, low confidence (0.02); PolyPhen benign (0); catalogued as COSV100826834; called by muse, mutect2, varscan2
- LOXL1 | c.679C>T p.P227S | Missense Mutation (SNP) | VAF 12/69 reads (17%) | SIFT tolerated (0.09); PolyPhen probably damaging (0.992); catalogued as rs1318493338, COSV99985167; called by muse, mutect2, varscan2
- MAP2 | c.1331T>C p.L444P | Missense Mutation (SNP) | VAF 53/178 reads (30%) | SIFT tolerated, low confidence (0.41); PolyPhen benign (0.001); catalogued as COSV99557506; called by muse, mutect2, varscan2
- MCOLN3 | c.107A>G p.D36G | Missense Mutation (SNP) | VAF 24/77 reads (31%) | SIFT deleterious (0); PolyPhen benign (0.019); catalogued as COSV100352542; called by muse, mutect2, varscan2
- MUC5AC | c.1454C>T p.T485I | Missense Mutation (SNP) | VAF 9/58 reads (16%) | SIFT deleterious (0); catalogued as rs755414645, COSV100650513; called by muse, mutect2, varscan2
- MYO18B | c.427C>A p.P143T | Missense Mutation (SNP) | VAF 45/162 reads (28%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.998); catalogued as COSV100122452; called by muse, mutect2, varscan2
- NCAPH2 | c.1617G>T p.E539D | Missense Mutation (SNP) | VAF 32/76 reads (42%) | SIFT tolerated (0.38); PolyPhen benign (0.325); catalogued as COSV99329285; called by muse, mutect2, varscan2
- NOL4 | c.1805G>A p.S602N | Missense Mutation (SNP) | VAF 23/77 reads (30%) | SIFT tolerated (0.24); PolyPhen benign (0.007); catalogued as COSV99304802; called by muse, mutect2, varscan2
- NUDT19 | c.904A>G p.M302V | Missense Mutation (SNP) | VAF 18/54 reads (33%) | SIFT tolerated (0.49); PolyPhen benign (0.006); catalogued as rs767309152, COSV101229175; called by muse, mutect2, varscan2
- OR13G1 | c.659T>C p.V220A | Missense Mutation (SNP) | VAF 30/126 reads (24%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as COSV100687014; called by muse, mutect2, varscan2
- OR13H1 | c.814T>A p.F272I | Missense Mutation (SNP) | VAF 127/234 reads (54%) | SIFT tolerated (1); PolyPhen benign (0.009); catalogued as COSV100088108; called by muse, mutect2, varscan2
- OR51A7 | c.414C>A p.S138R | Missense Mutation (SNP) | VAF 32/87 reads (37%) | SIFT tolerated (0.36); PolyPhen possibly damaging (0.493); catalogued as COSV100834577; called by muse, mutect2, varscan2
- OR8H2 | c.353T>A p.M118K | Missense Mutation (SNP) | VAF 30/104 reads (29%) | SIFT deleterious (0); PolyPhen possibly damaging (0.493); catalogued as COSV100542117; called by muse, mutect2, varscan2
- OSGEPL1 | c.964G>T p.V322F | Missense Mutation (SNP) | VAF 71/266 reads (27%) | SIFT deleterious (0); PolyPhen benign (0.219); catalogued as rs889260416, COSV99918276; called by muse, mutect2, varscan2
- PDE4D | c.94G>A p.G32R | Missense Mutation (SNP) | VAF 394/1371 reads (29%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.232); catalogued as rs756880197, COSV101550395; called by mutect2, varscan2
- PLTP | c.1069C>A p.P357T | Missense Mutation (SNP) | VAF 24/96 reads (25%) | SIFT deleterious (0.01); PolyPhen benign (0.342); catalogued as COSV99509615; called by muse, mutect2, varscan2
- PLXNA1 | c.2053G>A p.V685M | Missense Mutation (SNP) | VAF 12/66 reads (18%) | SIFT tolerated (0.23); PolyPhen benign (0.105); catalogued as rs767000075, COSV52523154; called by muse, mutect2, varscan2
- PLXNA4 | c.2623A>G p.K875E | Missense Mutation (SNP) | VAF 18/66 reads (27%) | SIFT deleterious (0.03); PolyPhen benign (0.102); catalogued as COSV100322211; called by muse, mutect2, varscan2
- PNISR | c.1496A>G p.H499R | Missense Mutation (SNP) | VAF 20/87 reads (23%) | SIFT tolerated, low confidence (0.62); PolyPhen benign (0.017); catalogued as rs544853512, COSV100984296; called by muse, mutect2, varscan2
- PTPRC | c.3763G>T p.V1255L | Missense Mutation (SNP) | VAF 96/328 reads (29%) | SIFT tolerated (0.13); PolyPhen benign (0.005); catalogued as COSV100722069; called by muse, mutect2, varscan2
- PXDC1 | c.31C>T p.L11F | Missense Mutation (SNP) | VAF 29/102 reads (28%) | SIFT deleterious, low confidence (0.01); PolyPhen possibly damaging (0.478); catalogued as rs1188303475, COSV100977346; called by muse, mutect2, varscan2
- RBM10 | c.186G>C p.E62D | Missense Mutation (SNP) | VAF 25/39 reads (64%) | SIFT tolerated (0.26); PolyPhen probably damaging (0.956); catalogued as COSV100237213; called by muse, mutect2, varscan2
- RCAN3 | c.370-1G>A p.X124_splice | Splice Site (SNP) | VAF 25/67 reads (37%) | catalogued as rs747514066, COSV100980319; called by muse, mutect2, varscan2
- REPS1 | c.1553C>G p.S518C (on ENST00000450536 / NM_001286611.2; = p.S517C on NM_031922.4) | Missense Mutation (SNP) | VAF 18/72 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); catalogued as COSV99238350; called by muse, mutect2, varscan2
- RIMKLA | c.601C>T p.R201W | Missense Mutation (SNP) | VAF 7/128 reads (5%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1257985060, COSV101290545, COSV68909828; called by muse, mutect2
- RIMS2 | c.4757G>T p.G1586V (on ENST00000666250 / NM_001348490.2; = p.G1157V on NM_014677.5 and 7 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 113/199 reads (57%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (1); catalogued as COSV99156686; called by muse, mutect2, varscan2
- RSPO2 | c.523C>T p.Q175* | Nonsense Mutation (SNP) | VAF 114/222 reads (51%) | catalogued as COSV99408869; called by muse, mutect2, varscan2
- S100A5 | c.194A>G p.Q65R | Missense Mutation (SNP) | VAF 26/114 reads (23%) | SIFT tolerated (0.09); PolyPhen benign (0); catalogued as rs769167385, COSV100785879, COSV104418778; called by muse, mutect2, varscan2
- SEL1L | c.2203A>G p.M735V | Missense Mutation (SNP) | VAF 38/128 reads (30%) | SIFT tolerated (0.2); PolyPhen benign (0.007); catalogued as COSV100377617; called by muse, mutect2, varscan2
- SLC1A6 | c.1315G>T p.A439S | Missense Mutation (SNP) | VAF 23/92 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (0.913); catalogued as COSV99693347; called by muse, mutect2, varscan2
- SLC23A2 | c.1570A>C p.I524L | Missense Mutation (SNP) | VAF 37/157 reads (24%) | SIFT tolerated (0.39); PolyPhen benign (0.01); catalogued as COSV100594740; called by muse, mutect2, varscan2
- SLC50A1 | c.119A>G p.D40G | Missense Mutation (SNP) | VAF 53/307 reads (17%) | SIFT tolerated (0.2); PolyPhen benign (0.003); catalogued as COSV100310195; called by muse, mutect2, varscan2
- SORL1 | c.6082G>A p.D2028N | Missense Mutation (SNP) | VAF 17/84 reads (20%) | SIFT tolerated (0.09); PolyPhen benign (0.115); catalogued as COSV99492708; called by muse, mutect2, varscan2
- SPTBN5 | c.7413A>T p.Q2471H | Missense Mutation (SNP) | VAF 5/34 reads (15%) | SIFT tolerated (0.05); PolyPhen probably damaging (0.919); catalogued as COSV100310557; called by muse, mutect2, varscan2
- SRCAP | c.6451C>T p.R2151C | Missense Mutation (SNP) | VAF 29/94 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV99349117; called by muse, mutect2, varscan2
- TEK | c.320G>T p.R107L | Missense Mutation (SNP) | VAF 50/148 reads (34%) | SIFT tolerated (0.28); PolyPhen possibly damaging (0.526); catalogued as COSV101193099; called by muse, mutect2, varscan2
- TLN1 | c.4829C>A p.A1610D | Missense Mutation (SNP) | VAF 9/43 reads (21%) | SIFT deleterious (0); PolyPhen benign (0.265); catalogued as COSV100147235; called by muse, mutect2, varscan2
- TNRC6A | c.473T>C p.I158T | Missense Mutation (SNP) | VAF 23/77 reads (30%) | SIFT tolerated (0.18); PolyPhen benign (0.107); catalogued as rs367544720, COSV100169368; called by muse, mutect2, varscan2
- TTI2 | c.1238T>G p.L413R | Missense Mutation (SNP) | VAF 30/74 reads (41%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.564); catalogued as COSV100659598; called by muse, mutect2, varscan2
- TTN | c.8758G>A p.E2920K (on ENST00000591111; = p.E2874K on NM_003319.4) | Missense Mutation (SNP) | VAF 35/145 reads (24%) | PolyPhen probably damaging (0.994); catalogued as rs911601060, COSV60097510; called by muse, mutect2, varscan2
- ULK3 | c.1186G>T p.E396* | Nonsense Mutation (SNP) | VAF 36/135 reads (27%) | catalogued as COSV101475535; called by muse, mutect2, varscan2
- ZNF142 | c.1248A>C p.E416D (on ENST00000411696 / NM_001379660.1; = p.E216D on NM_001105537.4 and 5 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 19/80 reads (24%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.515); catalogued as COSV101376891; called by muse, mutect2, varscan2
- ZNF254 | c.30+2T>C p.X10_splice | Splice Site (SNP) | VAF 7/92 reads (8%) | catalogued as COSV60055624; called by muse, mutect2
- ZNF292 | c.729G>T p.K243N | Missense Mutation (SNP) | VAF 39/168 reads (23%) | SIFT deleterious (0.01); PolyPhen benign (0.347); catalogued as COSV100369662; called by muse, mutect2, varscan2
- ZNF536 | c.1969C>A p.R657S | Missense Mutation (SNP) | VAF 37/116 reads (32%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.856); catalogued as COSV100834571; called by muse, mutect2, varscan2
- APOB | c.9723_9750delinsCTC p.E3241Dfs*17 | Frame Shift Del (DEL) | VAF 22/103 reads (21%) | called by pindel, varscan2*
- BEND3 | c.2092_2104del p.F698Pfs*131 | Frame Shift Del (DEL) | VAF 38/164 reads (23%) | called by mutect2, pindel, varscan2
- DGLUCY | c.1155_1163del p.I386_E388del | In Frame Del (DEL) | VAF 12/71 reads (17%) | called by mutect2, pindel, varscan2
- FLNC | c.6769_6777del p.P2257_G2259del | In Frame Del (DEL) | VAF 38/188 reads (20%) | called by mutect2, varscan2
- IFI30 | c.639del p.K213Nfs*42 | Frame Shift Del (DEL) | VAF 23/106 reads (22%) | called by mutect2, pindel, varscan2
- BPI | c.1041C>A p.I347= (on ENST00000262865; = p.I343= on NM_001725.3) | Silent (SNP) | VAF 18/49 reads (37%) | catalogued as rs1186272537, COSV53406754; called by muse, mutect2, varscan2
- CA12 | c.594G>A p.Q198= | Silent (SNP) | VAF 30/117 reads (26%) | catalogued as COSV99457844; called by muse, mutect2, varscan2
- CDC7 | c.1275C>T p.A425= | Silent (SNP) | VAF 28/148 reads (19%) | catalogued as rs1368701219, COSV99319519; called by muse, mutect2, varscan2
- CDHR1 | c.1392C>T p.D464= | Silent (SNP) | VAF 31/120 reads (26%) | catalogued as COSV100258327, COSV60567028; called by muse, mutect2, varscan2
- CLASP1 | c.2551C>T p.L851= | Silent (SNP) | VAF 41/176 reads (23%) | catalogued as COSV99752694; called by muse, mutect2, varscan2
- COL4A4 | c.1884G>A p.G628= | Silent (SNP) | VAF 54/163 reads (33%) | catalogued as rs761646265, COSV100306098; called by muse, mutect2, varscan2
- COPG1 | c.789C>T p.H263= | Silent (SNP) | VAF 22/73 reads (30%) | catalogued as rs377596678; called by muse, mutect2, varscan2
- CYP20A1 | c.963G>A p.E321= | Silent (SNP) | VAF 131/560 reads (23%) | catalogued as COSV100618994; called by muse, mutect2, varscan2
- DUSP1 | c.828T>C p.T276= | Silent (SNP) | VAF 8/92 reads (9%) | catalogued as COSV99495835; called by muse, mutect2
- EPG5 | c.3291G>A p.Q1097= | Silent (SNP) | VAF 17/51 reads (33%) | catalogued as COSV56349283, COSV99956391; called by muse, mutect2, varscan2
- ERBB3 | c.24G>A p.Q8= | Silent (SNP) | VAF 49/125 reads (39%) | catalogued as COSV99915607; called by muse, mutect2, varscan2
- FAM149A | c.2055A>G p.L685= (on ENST00000356371 / NM_001367768.2; = p.L394= on NM_015398.3 and 3 other RefSeq transcripts) | Silent (SNP) | VAF 78/242 reads (32%) | catalogued as COSV99906275; called by muse, mutect2, varscan2
- GABRG3 | c.1377C>A p.V459= | Silent (SNP) | VAF 30/88 reads (34%) | catalogued as COSV100404490; called by muse, mutect2, varscan2
- IL2RA | c.618T>C p.R206= | Silent (SNP) | VAF 15/60 reads (25%) | catalogued as COSV99906451; called by muse, mutect2, varscan2
- KAT6B | c.5346T>A p.A1782= | Silent (SNP) | VAF 24/60 reads (40%) | catalogued as COSV99767247; called by muse, mutect2, varscan2
- MCEE | c.93A>G p.T31= | Silent (SNP) | VAF 13/77 reads (17%) | catalogued as rs954713172, COSV99730924; called by muse, mutect2, varscan2
- MTFR1 | c.453T>G p.L151= | Silent (SNP) | VAF 188/321 reads (59%) | catalogued as COSV100049989; called by muse, mutect2, varscan2
- NPAT | c.1011A>T p.T337= | Silent (SNP) | VAF 14/56 reads (25%) | catalogued as COSV99585732; called by muse, mutect2, varscan2
- NPTX2 | c.801C>G p.P267= | Silent (SNP) | VAF 20/42 reads (48%) | catalogued as rs779765826, COSV99674668; called by muse, mutect2, varscan2
- OR10G2 | c.576G>A p.L192= | Silent (SNP) | VAF 68/269 reads (25%) | catalogued as COSV101606929; called by muse, varscan2
- PADI1 | c.1380C>G p.P460= | Silent (SNP) | VAF 22/76 reads (29%) | catalogued as COSV100968968; called by muse, mutect2, varscan2
- PCDH7 | c.708C>T p.N236= | Silent (SNP) | VAF 11/34 reads (32%) | catalogued as COSV100687415; called by muse, mutect2
- PCDHGB3 | c.1587G>A p.E529= | Silent (SNP) | VAF 25/87 reads (29%) | catalogued as COSV99529463; called by muse, mutect2, varscan2
- PLCXD2 | c.69G>A p.G23= | Silent (SNP) | VAF 37/172 reads (22%) | catalogued as COSV101209964; called by muse, mutect2, varscan2
- PRDM14 | c.159C>T p.F53= | Silent (SNP) | VAF 21/99 reads (21%) | catalogued as COSV99399828; called by muse, mutect2, varscan2
- TENT5A | c.1008G>A p.L336= | Silent (SNP) | VAF 31/110 reads (28%) | catalogued as COSV100198730; called by muse, mutect2, varscan2
- TNFAIP3 | c.2289G>T p.R763= | Silent (SNP) | VAF 37/131 reads (28%) | catalogued as COSV99396267; called by muse, mutect2, varscan2
- TNN | c.150G>A p.V50= | Silent (SNP) | VAF 27/123 reads (22%) | catalogued as rs1388007949, COSV99510987; called by muse, mutect2, varscan2
- UBC | c.1161C>T p.T387= | Silent (SNP) | VAF 59/247 reads (24%) | catalogued as rs767352362, COSV100298766; called by muse, varscan2
- URI1 | c.1533T>G p.V511= | Silent (SNP) | VAF 36/136 reads (26%) | catalogued as COSV100368795; called by muse, mutect2, varscan2
- VPS13B | c.1464G>T p.T488= | Silent (SNP) | VAF 135/216 reads (63%) | catalogued as COSV100660756, COSV62025717; called by muse, mutect2, varscan2
